Somatic mutation profile of tumor specimen TCGA-ZB-A969-01A (aliquot TCGA-ZB-A969-01A-11D-A428-09) from TCGA case TCGA-ZB-A969, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymic carcinoma, NOS; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 72.4 years (26,458 days).
Specimen TCGA-ZB-A969-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76dd9679-ca2c-49c2-824a-8f63be16c83c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZB-A969-11A (Solid Tissue Normal), aliquot TCGA-ZB-A969-11A-11D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db4eb5e0-1e85-4885-9c30-c4b4915b9309

The open-access MAF lists 24 somatic variants for this specimen: 20 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 16, Silent 4, Frame Shift Del 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 185/499 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- MAP4K2 | c.1684C>T p.R562W | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs772184647; called by muse, mutect2, varscan2
- NLGN4X | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99322225; called by muse, mutect2, varscan2
- NR4A2 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59892472; called by muse, mutect2, varscan2
- SAFB2 | c.2392C>G p.Q798E | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV53044689; called by muse, mutect2, varscan2
- SLC7A14 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.042); catalogued as rs530931888, COSV51582793, COSV51585816; called by muse, mutect2, varscan2
- TENT5C | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs557599465; called by muse, mutect2, varscan2
- TMEM132D | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.808); catalogued as rs1287424489, COSV70603146; called by muse, mutect2, varscan2
- VHL | c.527G>T p.R176M | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV56568222; called by muse, mutect2
- ZNF569 | c.1601T>C p.I534T | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.888); catalogued as rs760381789; called by muse, mutect2, varscan2
- ACSS1 | c.678_688del p.R227Afs*7 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- AIFM3 | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); called by muse, mutect2
- DNAH5 | c.1094C>T p.S365F | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- DTX3L | c.1853_1860del p.T618Kfs*8 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- DUS3L | c.1139T>C p.L380P | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GPR119 | c.15C>A p.F5L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITIH4 | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- PDE4B | c.230_231insAA p.P78Sfs*3 | Frame Shift Ins (INS) | VAF 8/46 reads (17%) | called by mutect2, pindel*, varscan2
- TBCEL | c.1255G>A p.V419M | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- WNK2 | c.4984A>G p.K1662E (on ENST00000297954 / NM_001282394.1; = p.K1625E on NM_006648.3) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.815); called by muse, mutect2
- DPY19L1 | c.1686T>C p.V562= | Silent (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- STARD8 | c.2838G>A p.P946= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as rs373631827; called by muse, mutect2, varscan2
- ZNF211 | c.855T>C p.Y285= (on ENST00000347302 / NM_198855.4; = p.Y298= on NM_006385.5) | Silent (SNP) | VAF 14/51 reads (27%) | called by muse, mutect2, varscan2
- ZNF574 | c.1998C>G p.R666= | Silent (SNP) | VAF 11/17 reads (65%) | called by muse, mutect2, varscan2
